Gene-level copy-number profile of tumor specimen C3N-03426-01 from CPTAC case C3N-03426, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 68.4 years (24,994 days).
Specimen C3N-03426-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67046000-0d4f-478a-a014-6e57cc5ebf61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03426-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/001cb7d2-1ab2-4809-84a2-02bdeeac8f0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,175; copy number 2: 44,165; copy number 3: 6,719; copy number 4: 102; copy number 5: 1; copy number 6: 54; copy number 7: 42; copy number 9: 11; copy number 10: 64; copy number 12: 6; copy number 13: 4; copy number 16: 42; copy number 28: 12.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:71,814,045–71,821,548, 1 gene (within-gene range 0–2): ZNF705E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 236 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,375,985–39,747,291, 96 genes, copy number 5–28 (within-gene range 1–28) (broad region; genes not listed).
- chr17:40,624,962–42,578,366, 140 genes, copy number 6–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
